Somatic mutation profile of tumor specimen MMRF_2436_1_BM_CD138pos (aliquot MMRF_2436_1_BM_CD138pos_T1_KHS5U_K15186) from MMRF case MMRF_2436, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 60.2 years (21,990 days).
Specimen MMRF_2436_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 136cbe00-9669-4e2f-8b59-180293f16fd7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2436_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2436_1_PB_Whole_C3_KHS5U_K15187; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2012dd33-8ad3-4e25-a811-a8bfa66a96e9

The open-access MAF lists 168 somatic variants for this specimen: 60 protein-altering or splice-affecting, 23 silent, 85 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 52, 3'UTR 44, Silent 23, Intron 22, 5'Flank 7, 5'UTR 7, Splice Site 4, Nonsense Mutation 3, RNA 3, 3'Flank 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1906G>C p.G636R (on ENST00000288602 / NM_001374244.1; = p.G596R on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.316); catalogued as rs121913361, COSV56066561, COSV56185580, COSV56316158, COSV99954791; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- CLN3 | c.916G>A p.V306I (on ENST00000360019 / NM_001286104.2; = p.V330I on NM_000086.2) | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs386833744, CM970336; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2
- ADAMTS13 | c.3272G>A p.G1091D | Missense Mutation (SNP) | VAF 5/142 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1554795403, COSV52469827, COSV52470680; called by muse, mutect2
- CACNA1A | c.36C>G p.Y12* | Nonsense Mutation (SNP) | VAF 46/96 reads (48%) | catalogued as COSV100803236; called by muse, mutect2
- CDCP1 | c.1603G>C p.V535L | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.041); catalogued as COSV56106425; called by muse, mutect2, varscan2
- IGLV5-45 | c.65T>C p.V22A | Missense Mutation (SNP) | VAF 193/204 reads (95%) | SIFT deleterious (0.02); PolyPhen benign (0.19); catalogued as rs755243682; called by muse, mutect2, varscan2
- KCNA7 | c.631G>A p.V211M | Missense Mutation (SNP) | VAF 43/106 reads (41%) | SIFT tolerated (0.26); PolyPhen benign (0.275); catalogued as rs531366512, COSV55503984; called by muse, mutect2, varscan2
- LRP2 | c.7391-2A>C p.X2464_splice | Splice Site (SNP) | VAF 52/390 reads (13%) | catalogued as COSV55562988; called by muse, mutect2, varscan2
- MED10 | c.265C>G p.L89V | Missense Mutation (SNP) | VAF 50/98 reads (51%) | SIFT tolerated (0.11); PolyPhen benign (0.287); catalogued as COSV99740296; called by muse, mutect2, varscan2
- MGAM2 | c.2023C>A p.L675I | Missense Mutation (SNP) | VAF 6/148 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.843); catalogued as rs772032999; called by muse, mutect2
- MUC6 | c.3265G>A p.A1089T | Missense Mutation (SNP) | VAF 69/136 reads (51%) | SIFT tolerated (0.44); PolyPhen benign (0.057); catalogued as rs375978389, COSV101424663, COSV70142424; called by muse, mutect2, varscan2
- NTRK1 | c.1972G>C p.V658L | Missense Mutation (SNP) | VAF 79/195 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.051); catalogued as COSV62327932; called by muse, mutect2, varscan2
- NUDT7 | c.477C>A p.D159E | Missense Mutation (SNP) | VAF 11/105 reads (10%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as rs757485666; called by muse, mutect2, varscan2
- PCDHGA8 | c.638C>T p.T213M | Missense Mutation (SNP) | VAF 92/110 reads (84%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.48); catalogued as rs756966401, COSV53912071; called by muse, mutect2, varscan2
- PLXNA2 | c.5521G>A p.A1841T | Missense Mutation (SNP) | VAF 94/184 reads (51%) | SIFT tolerated (0.55); PolyPhen benign (0.183); catalogued as rs758935682, COSV65440264; called by muse, mutect2, varscan2
- RNF213 | c.6454C>G p.P2152A | Missense Mutation (SNP) | VAF 12/170 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60398536; called by muse, mutect2
- TDRD12 | c.3064C>T p.H1022Y (on ENST00000444215; = p.H1027Y on NM_001366102.1) | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as rs75360651; called by muse, mutect2, varscan2
- TENM2 | c.5924C>A p.S1975Y (on ENST00000518659 / NM_001122679.2; = p.S1736Y on NM_001080428.3) | Missense Mutation (SNP) | VAF 5/87 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV69129879; called by muse, mutect2
- TMEM79 | c.1117G>A p.E373K | Missense Mutation (SNP) | VAF 106/240 reads (44%) | SIFT tolerated (0.28); PolyPhen benign (0.093); catalogued as rs1317831609, COSV55293897; called by muse, mutect2, varscan2
- TNS3 | c.344G>T p.G115V | Missense Mutation (SNP) | VAF 31/105 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60786764; called by muse, mutect2, varscan2
- UMPS | c.854A>G p.D285G | Missense Mutation (SNP) | VAF 51/133 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99228653; called by muse, mutect2, varscan2
- ARMCX1 | c.1358T>C p.L453P | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- C5orf38 | c.41G>A p.R14H | Missense Mutation (SNP) | VAF 4/74 reads (5%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.139); called by muse, mutect2
- CCER2 | c.105G>C p.L35= | Splice Region (SNP) | VAF 19/58 reads (33%) | called by muse, mutect2, varscan2
- CEP131 | c.1504G>A p.A502T (on ENST00000269392 / NM_001319228.2; = p.A499T on NM_014984.4) | Missense Mutation (SNP) | VAF 78/123 reads (63%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.521); called by muse, mutect2, varscan2
- CFTR | c.1929A>T p.K643N | Missense Mutation (SNP) | VAF 72/181 reads (40%) | SIFT tolerated (0.34); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- COL12A1 | c.8507G>A p.G2836E | Missense Mutation (SNP) | VAF 70/152 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL9A2 | c.334C>T p.L112F | Missense Mutation (SNP) | VAF 9/239 reads (4%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.939); called by muse, mutect2
- DDO | c.722A>G p.D241G (on ENST00000368924 / NM_001368172.1; = p.D182G on NM_004032.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/153 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.817); called by muse, mutect2
- EGFLAM | c.1646C>A p.P549H | Missense Mutation (SNP) | VAF 70/168 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); called by muse, mutect2
- EPRS1 | c.3390T>A p.Y1130* | Nonsense Mutation (SNP) | VAF 17/236 reads (7%) | called by muse, mutect2
- FAM193A | c.417C>G p.I139M | Missense Mutation (SNP) | VAF 6/89 reads (7%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); called by muse, mutect2
- FAT3 | c.5348C>A p.P1783Q | Missense Mutation (SNP) | VAF 11/216 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2
- FTCD | c.1040T>A p.V347E | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- JAKMIP2 | c.257A>T p.Q86L | Missense Mutation (SNP) | VAF 31/169 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- KCNA1 | c.1348A>T p.S450C | Missense Mutation (SNP) | VAF 26/133 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- LMX1A | c.669+2T>C p.X223_splice | Splice Site (SNP) | VAF 22/48 reads (46%) | called by muse, varscan2
- LRIG2 | c.2933T>A p.I978K | Missense Mutation (SNP) | VAF 71/201 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- MAMDC2 | c.995-2A>C p.X332_splice | Splice Site (SNP) | VAF 73/146 reads (50%) | called by muse, mutect2, varscan2
- MYO10 | c.3092A>T p.E1031V | Missense Mutation (SNP) | VAF 20/184 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.236); called by muse, mutect2, varscan2
- NKG7 | c.292G>A p.A98T | Missense Mutation (SNP) | VAF 10/160 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.782); called by muse, mutect2
- OR13G1 | c.73T>A p.F25I | Missense Mutation (SNP) | VAF 20/262 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.298); called by muse, mutect2
- PALM2AKAP2 | c.545T>G p.V182G (on ENST00000374531 / NM_001037293.2; = p.V214G on NM_053016.6) | Missense Mutation (SNP) | VAF 15/141 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.419); called by muse, mutect2, varscan2
- PCDH7 | c.1678A>G p.T560A | Missense Mutation (SNP) | VAF 12/251 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.034); called by muse, mutect2
- PCDHGB4 | c.1594G>A p.A532T | Missense Mutation (SNP) | VAF 33/47 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PEX14 | c.363T>G p.F121L | Missense Mutation (SNP) | VAF 65/196 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.672); called by muse, mutect2, varscan2
- PGM3 | c.695T>C p.L232P | Missense Mutation (SNP) | VAF 12/216 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); called by muse, mutect2
- PKD1L1 | c.4364G>T p.G1455V | Missense Mutation (SNP) | VAF 18/136 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.424); called by muse, mutect2, varscan2
- PPP2R2A | c.180+2dup p.X60_splice | Splice Site (INS) | VAF 3/32 reads (9%) | called by mutect2, pindel
- PTPRT | c.2430G>C p.K810N | Missense Mutation (SNP) | VAF 46/122 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by mutect2, varscan2
- RPS6KB2 | c.127G>T p.G43* | Nonsense Mutation (SNP) | VAF 93/170 reads (55%) | called by muse, mutect2, varscan2
- SCML2 | c.1957G>C p.D653H | Missense Mutation (SNP) | VAF 30/35 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SEC63 | c.467A>C p.E156A | Missense Mutation (SNP) | VAF 9/141 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); called by muse, mutect2
- SNTG1 | c.1477C>A p.L493I | Missense Mutation (SNP) | VAF 203/209 reads (97%) | SIFT tolerated (0.39); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SUMF1 | c.815A>G p.E272G | Missense Mutation (SNP) | VAF 6/105 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.281); called by muse, mutect2
- SYNE2 | c.11078A>G p.E3693G | Missense Mutation (SNP) | VAF 35/36 reads (97%) | SIFT deleterious (0.03); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- TRPC4 | c.1993T>C p.S665P | Missense Mutation (SNP) | VAF 58/60 reads (97%) | SIFT deleterious (0.01); PolyPhen benign (0.302); called by muse, mutect2, varscan2
- UNC93B1 | c.991C>T p.P331S | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- WWC1 | c.95C>T p.T32I | Missense Mutation (SNP) | VAF 25/226 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- ZNF676 | c.1788A>T p.E596D (on ENST00000650058; = p.E564D on NM_001001411.3) | Missense Mutation (SNP) | VAF 8/168 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.166); called by muse, mutect2
- ABI3BP | c.2232G>A p.R744= | Silent (SNP) | VAF 11/89 reads (12%) | catalogued as rs1278865276; called by muse, mutect2, varscan2
- ANTXR1 | c.1137C>T p.D379= | Silent (SNP) | VAF 65/129 reads (50%) | catalogued as rs775392233, COSV58011787; called by muse, mutect2, varscan2
- ANXA6 | c.687C>T p.S229= | Silent (SNP) | VAF 17/109 reads (16%) | catalogued as rs765981759; called by muse, mutect2, varscan2
- ATP13A5 | c.2091G>A p.L697= | Silent (SNP) | VAF 34/206 reads (17%) | called by muse, mutect2, varscan2
- BAZ2B | c.2673T>G p.A891= | Silent (SNP) | VAF 17/130 reads (13%) | called by muse, mutect2, varscan2
- CFD | c.390G>C p.V130= | Silent (SNP) | VAF 6/65 reads (9%) | called by muse, mutect2, varscan2
- CHRM4 | c.906C>A p.T302= | Silent (SNP) | VAF 8/112 reads (7%) | catalogued as COSV100708864; called by muse, mutect2
- CILP2 | c.1470C>T p.F490= | Silent (SNP) | VAF 27/64 reads (42%) | catalogued as COSV52272792; called by muse, mutect2, varscan2
- CYP27A1 | c.1098G>A p.V366= | Silent (SNP) | VAF 59/139 reads (42%) | catalogued as rs905020402; called by muse, mutect2, varscan2
- DRD2 | c.141C>T p.V47= | Silent (SNP) | VAF 10/272 reads (4%) | catalogued as COSV60753904; called by muse, mutect2
- FES | c.526C>T p.L176= | Silent (SNP) | VAF 11/282 reads (4%) | catalogued as rs1189245913; called by muse, mutect2
- GLI1 | c.336G>A p.S112= | Silent (SNP) | VAF 16/297 reads (5%) | catalogued as rs371273350, COSV57360730; called by muse, mutect2
- GNL2 | c.1639C>T p.L547= | Silent (SNP) | VAF 57/158 reads (36%) | called by muse, mutect2, varscan2
- IGLV7-46 | c.219C>T p.S73= | Silent (SNP) | VAF 38/43 reads (88%) | catalogued as rs144951017; called by muse, mutect2, varscan2
- LRP6 | c.1875G>A p.K625= | Silent (SNP) | VAF 6/114 reads (5%) | called by muse, mutect2
- NRCAM | c.3813C>T p.S1271= (on ENST00000379028 / NM_001371124.1; = p.S1150= on NM_005010.4 and 21 other RefSeq transcripts) | Silent (SNP) | VAF 20/398 reads (5%) | catalogued as rs751752831, COSV61049080; called by muse, mutect2
- NUP160 | c.2460G>A p.Q820= | Silent (SNP) | VAF 9/99 reads (9%) | called by muse, mutect2, varscan2
- POLD4 | c.81G>A p.E27= | Silent (SNP) | VAF 57/144 reads (40%) | called by muse, mutect2, varscan2
- SASH1 | c.3048G>A p.A1016= | Silent (SNP) | VAF 75/145 reads (52%) | catalogued as rs752540259, COSV66560292; called by muse, mutect2, varscan2
- TEAD1 | c.1071A>G p.P357= | Silent (SNP) | VAF 8/240 reads (3%) | called by muse, mutect2
- UVRAG | c.768A>G p.K256= | Silent (SNP) | VAF 50/129 reads (39%) | called by muse, mutect2, varscan2
- ZNF541 | c.1584C>T p.G528= | Silent (SNP) | VAF 85/148 reads (57%) | catalogued as rs1288748288; called by muse, mutect2, varscan2
- ZNF74 | c.543C>T p.L181= | Silent (SNP) | VAF 68/71 reads (96%) | catalogued as COSV100677414, COSV100677560; called by muse, mutect2, varscan2
- ABL2 | c.*4186del | 3'UTR (DEL) | VAF 28/105 reads (27%) | called by mutect2, pindel, varscan2
- AC009729.1 | n.688A>G | RNA (SNP) | VAF 41/106 reads (39%) | called by muse, mutect2, varscan2
- AC093334.1 | n.186C>T | RNA (SNP) | VAF 160/261 reads (61%) | called by muse, mutect2, varscan2
- ACOT7 | c.174-9386G>A | Intron (SNP) | VAF 20/87 reads (23%) | called by muse, mutect2, varscan2
- ADRB2 | c.-168G>A | 5'UTR (SNP) | VAF 99/267 reads (37%) | called by muse, mutect2, varscan2
- ANXA11 | c.*3222A>G | 3'UTR (SNP) | VAF 30/82 reads (37%) | called by muse, mutect2, varscan2
- ARHGAP20 | c.*1408G>T | 3'UTR (SNP) | VAF 43/98 reads (44%) | called by muse, mutect2, varscan2
- ARHGAP31 | c.*2574T>A | 3'UTR (SNP) | VAF 61/127 reads (48%) | called by muse, mutect2, varscan2
- ARMS2 | c.*41C>A | 3'UTR (SNP) | VAF 114/252 reads (45%) | called by muse, mutect2, varscan2
- BEND7 | c.1082-2536C>A | Intron (SNP) | VAF 6/132 reads (5%) | called by muse, mutect2
- CCDC85C | c.*313G>C | 3'UTR (SNP) | VAF 15/57 reads (26%) | called by muse, mutect2, varscan2
- CDH12 | c.*300A>G | 3'UTR (SNP) | VAF 10/57 reads (18%) | called by muse, mutect2, varscan2
- CFAP47 | c.9354+99A>G | Intron (SNP) | VAF 5/26 reads (19%) | called by muse, mutect2, varscan2
- CNTNAP5 | c.-163C>T | 5'UTR (SNP) | VAF 35/70 reads (50%) | called by muse, mutect2, varscan2
- CREB3L2 | c.*4076T>G | 3'UTR (SNP) | VAF 15/36 reads (42%) | called by muse, mutect2, varscan2
- CSF3 | c.40+70G>A | Intron (SNP) | VAF 6/30 reads (20%) | called by muse, mutect2
- CTBP2 | c.59-2492G>A | Intron (SNP) | VAF 6/82 reads (7%) | catalogued as rs932391139; called by muse, mutect2
- DUSP8 | c.*385del | 3'UTR (DEL) | VAF 25/51 reads (49%) | catalogued as rs1012402340; called by mutect2, varscan2
- FAM120AOS | c.-859A>G | 5'UTR (SNP) | VAF 19/42 reads (45%) | called by muse, mutect2, varscan2
- FER | c.*1263C>T | 3'UTR (SNP) | VAF 4/97 reads (4%) | called by muse, mutect2
- FRAS1 | c.*568G>T | 3'UTR (SNP) | VAF 6/110 reads (5%) | called by muse, mutect2
- GAD2 | c.*35-801C>A | Intron (SNP) | VAF 13/75 reads (17%) | called by muse, mutect2, varscan2
- GLIPR2 | chr9:36136667 C>T | 5'Flank (SNP) | VAF 8/21 reads (38%) | catalogued as rs1409115741; called by muse, mutect2, varscan2
- GOLPH3L | c.*1381A>C | 3'UTR (SNP) | VAF 11/107 reads (10%) | called by muse, mutect2
- GRM4 | c.-109C>G | 5'UTR (SNP) | VAF 23/128 reads (18%) | catalogued as COSV65219364; called by muse, mutect2, varscan2
- GTPBP8 | c.336+19G>T | Intron (SNP) | VAF 9/232 reads (4%) | called by muse, mutect2
- GXYLT1 | c.*5669T>C | 3'UTR (SNP) | VAF 28/85 reads (33%) | catalogued as rs929110579; called by muse, mutect2, varscan2
- H3C15 | chr1:149850366 C>G | 5'Flank (SNP) | VAF 22/68 reads (32%) | called by muse, mutect2, varscan2
- HBS1L | c.*1484A>C | 3'UTR (SNP) | VAF 5/113 reads (4%) | called by muse, mutect2
- HELZ | c.*13T>C | 3'UTR (SNP) | VAF 27/50 reads (54%) | called by muse, mutect2, varscan2
- ILRUN | c.-13T>C | 5'UTR (SNP) | VAF 53/129 reads (41%) | called by muse, mutect2, varscan2
- IPO9 | c.*845G>A | 3'UTR (SNP) | VAF 42/81 reads (52%) | called by muse, mutect2, varscan2
- ITGB3BP | chr1:63523282 C>G | 5'Flank (SNP) | VAF 25/71 reads (35%) | called by muse, mutect2
- KASH5 | c.798+48G>A | Intron (SNP) | VAF 19/61 reads (31%) | called by muse, mutect2, varscan2
- KTN1 | chr14:55576914 A>T | 5'Flank (SNP) | VAF 33/45 reads (73%) | called by muse, mutect2, varscan2
- LARP1B | c.988+297C>T | Intron (SNP) | VAF 33/67 reads (49%) | called by muse, mutect2, varscan2
- LIFR | c.*5958G>T | 3'UTR (SNP) | VAF 19/41 reads (46%) | called by muse, mutect2, varscan2
- LILRB4 | chr19:54669644 C>A | 3'Flank (SNP) | VAF 79/162 reads (49%) | called by muse, mutect2, varscan2
- LMBRD2 | c.*2293T>G | 3'UTR (SNP) | VAF 6/67 reads (9%) | called by muse, mutect2
- LTB | c.163-102G>A | Intron (SNP) | VAF 160/364 reads (44%) | called by muse, mutect2, varscan2
- MACROH2A1 | c.779-299G>C | Intron (SNP) | VAF 53/121 reads (44%) | called by muse, mutect2, varscan2
- MCHR2 | c.*226G>A | 3'UTR (SNP) | VAF 44/84 reads (52%) | called by muse, mutect2, varscan2
- MICALL2 | c.*25C>T | 3'UTR (SNP) | VAF 88/217 reads (41%) | called by muse, mutect2, varscan2
- MIR22 | chr17:1716697 C>T | 5'Flank (SNP) | VAF 16/268 reads (6%) | catalogued as rs890604133; called by muse, mutect2
- MIR5195 | chr14:106851315 C>G | 5'Flank (SNP) | VAF 108/111 reads (97%) | catalogued as rs537569481; called by muse, mutect2, varscan2
- MPPED2 | c.*102C>T | 3'UTR (SNP) | VAF 16/77 reads (21%) | called by muse, mutect2, varscan2
- NCK2 | c.*991C>T | 3'UTR (SNP) | VAF 33/72 reads (46%) | catalogued as rs1445346615; called by muse, mutect2, varscan2
- NRCAM | c.*156C>A | 3'UTR (SNP) | VAF 12/140 reads (9%) | called by muse, mutect2
- PAK5 | c.*1839G>A | 3'UTR (SNP) | VAF 9/40 reads (23%) | called by muse, mutect2, varscan2
- PDCD6IP | c.*2992G>T | 3'UTR (SNP) | VAF 8/62 reads (13%) | called by muse, mutect2, varscan2
- PEG10 | c.*3516C>T | 3'UTR (SNP) | VAF 8/70 reads (11%) | called by muse, mutect2, varscan2
- POLD4 | c.188-89G>C | Intron (SNP) | VAF 48/117 reads (41%) | called by muse, mutect2, varscan2
- POLD4 | c.188-90G>A | Intron (SNP) | VAF 47/118 reads (40%) | called by muse, mutect2, varscan2
- PTPRN | c.281-83G>A | Intron (SNP) | VAF 22/61 reads (36%) | called by muse, mutect2, varscan2
- RAB27B | c.*2786G>T | 3'UTR (SNP) | VAF 42/79 reads (53%) | called by muse, mutect2, varscan2
- RAB35 | c.*1136G>A | 3'UTR (SNP) | VAF 12/135 reads (9%) | catalogued as rs1343752863; called by muse, mutect2
- RAG1 | c.*2847T>C | 3'UTR (SNP) | VAF 9/92 reads (10%) | called by muse, mutect2
- RPA1 | c.*1960C>T | 3'UTR (SNP) | VAF 94/215 reads (44%) | called by muse, mutect2, varscan2
- RS1 | c.*599G>A | 3'UTR (SNP) | VAF 62/65 reads (95%) | called by muse, mutect2, varscan2
- RTN1 | c.1766-23217G>T | Intron (SNP) | VAF 6/12 reads (50%) | called by muse, mutect2, varscan2
- SDK1 | c.1994+95C>A | Intron (SNP) | VAF 5/44 reads (11%) | called by muse, mutect2
- SEPSECS | c.*798C>G | 3'UTR (SNP) | VAF 4/55 reads (7%) | called by muse, mutect2
- SETDB1 | c.1140+119G>T | Intron (SNP) | VAF 6/139 reads (4%) | catalogued as COSV54986806; called by muse, mutect2
- SIRT2 | c.747+69A>G | Intron (SNP) | VAF 9/24 reads (38%) | called by muse, mutect2, varscan2
- SLC22A14 | c.775+78T>G | Intron (SNP) | VAF 10/26 reads (38%) | called by muse, mutect2
- SLC37A2 | c.*307G>C | 3'UTR (SNP) | VAF 7/111 reads (6%) | called by muse, mutect2
- SOX6 | chr11:15968982 G>A | 3'Flank (SNP) | VAF 21/53 reads (40%) | catalogued as rs955924111; called by muse, mutect2, varscan2
- SPATA18 | c.*158G>A | 3'UTR (SNP) | VAF 68/139 reads (49%) | catalogued as rs1371543516; called by muse, mutect2, varscan2
- SPATA5L1 | c.-91C>G | 5'UTR (SNP) | VAF 22/124 reads (18%) | catalogued as COSV99973067; called by muse, mutect2, varscan2
- SPIRE1 | c.*1962T>A | 3'UTR (SNP) | VAF 39/80 reads (49%) | called by muse, mutect2, varscan2
- SSPOP | n.8974G>T | RNA (SNP) | VAF 6/39 reads (15%) | catalogued as COSV65137807; called by muse, varscan2
- STAMBP | c.*3644G>A | 3'UTR (SNP) | VAF 6/135 reads (4%) | called by muse, mutect2
- STXBP6 | c.*457A>T | 3'UTR (SNP) | VAF 4/26 reads (15%) | called by muse, mutect2, varscan2
- TEDC1 | chr14:105491140 G>T | 5'Flank (SNP) | VAF 8/163 reads (5%) | called by muse, mutect2
- TLCD3A | c.123-151C>A | Intron (SNP) | VAF 8/27 reads (30%) | catalogued as rs1431839918; called by muse, mutect2, varscan2
- TMEM236 | c.*4026C>T | 3'UTR (SNP) | VAF 13/456 reads (3%) | called by muse, mutect2
- TMTC3 | c.*1629_*1630insC | 3'UTR (INS) | VAF 11/31 reads (35%) | called by mutect2*, varscan2
- TMX1 | c.*1406T>C | 3'UTR (SNP) | VAF 39/40 reads (98%) | catalogued as rs1273597690; called by muse, mutect2, varscan2
- TRIB1 | c.*1276_*1283del | 3'UTR (DEL) | VAF 10/72 reads (14%) | called by mutect2, pindel, varscan2
- TSPAN15 | c.*342A>T | 3'UTR (SNP) | VAF 30/81 reads (37%) | called by muse, mutect2
- ZFAND6 | c.*342T>C | 3'UTR (SNP) | VAF 68/469 reads (14%) | catalogued as rs189624188; called by muse, mutect2, varscan2
- ZNF510 | c.*493G>T | 3'UTR (SNP) | VAF 7/68 reads (10%) | called by muse, mutect2
- ZNF587 | c.34-42C>A | Intron (SNP) | VAF 71/173 reads (41%) | called by muse, mutect2, varscan2
- ZNF638 | c.2378-877C>G | Intron (SNP) | VAF 91/240 reads (38%) | catalogued as COSV100039833; called by muse, mutect2, varscan2
- ZNF844 | c.-106C>T | 5'UTR (SNP) | VAF 12/256 reads (5%) | catalogued as rs997782393, COSV101462782, COSV71518360; called by muse, mutect2
